Somatic mutation profile of tumor specimen C3L-00973-03 (aliquot CPT0102450009) from CPTAC case C3L-00973, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G2; Age at diagnosis: 76.1 years (27,798 days).
Specimen C3L-00973-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 833d9d5f-427d-4717-b015-e1b988ef6129.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-00973-31 (Blood Derived Normal), aliquot CPT0101050002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/05f03f6d-0f5a-428d-b76e-85799f717093

The open-access MAF lists 34 somatic variants for this specimen: 23 protein-altering or splice-affecting, 6 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Silent 6, Frame Shift Del 4, 3'UTR 3, Nonsense Mutation 1, In Frame Del 1, Intron 1, Splice Region 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 136/498 reads (27%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- MSN | c.1123C>T p.L375F | Missense Mutation (SNP) | VAF 48/90 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1421920149; called by muse, mutect2, varscan2
- N4BP2 | c.964G>T p.E322* | Nonsense Mutation (SNP) | VAF 43/351 reads (12%) | catalogued as rs773346400, COSV99788510; called by muse, mutect2, varscan2
- PDHA2 | c.209G>A p.R70H | Missense Mutation (SNP) | VAF 23/210 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.473); catalogued as COSV99757318; called by muse, mutect2, varscan2
- PIK3CG | c.550C>T p.R184C | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.279); catalogued as rs1189118505, COSV63248762, COSV63250737; called by muse, mutect2, varscan2
- SHC2 | c.1090G>A p.A364T | Missense Mutation (SNP) | VAF 13/113 reads (12%) | SIFT tolerated (0.23); PolyPhen benign (0.006); catalogued as rs747350066, COSV52750247; called by muse, mutect2, varscan2
- WNT7A | c.733C>T p.R245C | Missense Mutation (SNP) | VAF 14/181 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1559293096, COSV53197011; ClinVar: uncertain significance; called by muse, mutect2
- XRN1 | c.852G>T p.L284F | Missense Mutation (SNP) | VAF 35/256 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.75); catalogued as COSV53819153; called by muse, mutect2, varscan2
- ATP13A3 | c.1565T>C p.L522P | Missense Mutation (SNP) | VAF 19/129 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- BBS7 | c.1939C>G p.H647D | Missense Mutation (SNP) | VAF 32/324 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- BMP1 | c.833C>T p.S278F | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- C6orf163 | c.395A>T p.D132V | Missense Mutation (SNP) | VAF 30/308 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.081); called by muse, mutect2
- CCDC110 | c.219_233del p.L74_S78del | In Frame Del (DEL) | VAF 18/231 reads (8%) | called by mutect2, pindel
- KIAA1217 | c.4450del p.E1484Kfs*9 | Frame Shift Del (DEL) | VAF 30/344 reads (9%) | called by mutect2, pindel
- MACC1 | c.766G>T p.D256Y | Missense Mutation (SNP) | VAF 26/264 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.816); called by muse, mutect2
- NKX2-1 | c.823_830del p.P275Gfs*131 | Frame Shift Del (DEL) | VAF 10/70 reads (14%) | called by mutect2, pindel, varscan2
- PGBD2 | c.674T>G p.F225C | Missense Mutation (SNP) | VAF 68/433 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RAG1 | c.619del p.H207Tfs*57 | Frame Shift Del (DEL) | VAF 43/311 reads (14%) | called by mutect2, pindel, varscan2
- RB1 | c.1749_1752del p.D584Tfs*26 | Frame Shift Del (DEL) | VAF 30/332 reads (9%) | called by mutect2, pindel
- SEM1 | c.194C>A p.S65Y | Missense Mutation (SNP) | VAF 47/365 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.466); called by muse, mutect2, varscan2
- SMARCA2 | c.1047A>G p.R349= | Splice Region (SNP) | VAF 21/136 reads (15%) | called by muse, mutect2, varscan2
- SMCR8 | c.763T>C p.S255P | Missense Mutation (SNP) | VAF 27/217 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- UBE3B | c.224G>C p.C75S | Missense Mutation (SNP) | VAF 16/165 reads (10%) | SIFT tolerated (0.76); PolyPhen benign (0); called by muse, mutect2, varscan2
- DSCAML1 | c.1032G>A p.L344= (on ENST00000321322; = p.L284= on NM_020693.4) | Silent (SNP) | VAF 33/294 reads (11%) | called by muse, mutect2, varscan2
- FIZ1 | c.1074C>T p.Y358= | Silent (SNP) | VAF 44/258 reads (17%) | catalogued as rs767770032; called by muse, mutect2, varscan2
- MRGPRX2 | c.699C>T p.L233= | Silent (SNP) | VAF 26/258 reads (10%) | called by muse, mutect2
- PMM2 | c.531G>A p.Q177= | Silent (SNP) | VAF 64/471 reads (14%) | catalogued as rs771162235, CM051978; called by muse, mutect2, varscan2
- PXDNL | c.2742G>A p.S914= | Silent (SNP) | VAF 10/84 reads (12%) | catalogued as rs570625073, COSV62483560; called by muse, mutect2, varscan2
- SIRPD | c.593A>G p.*198= | Silent (SNP) | VAF 26/288 reads (9%) | called by muse, mutect2
- EMC4 | c.*28T>C | 3'UTR (SNP) | VAF 22/256 reads (9%) | catalogued as rs201082530; called by muse, mutect2
- MLX | c.*865G>T | 3'UTR (SNP) | VAF 27/281 reads (10%) | called by muse, mutect2
- OBP2A | c.-20G>A | 5'UTR (SNP) | VAF 13/157 reads (8%) | catalogued as rs1168101411; called by muse, mutect2, varscan2
- SFTPC | c.*69T>C | 3'UTR (SNP) | VAF 27/298 reads (9%) | catalogued as rs1458037882; called by muse, mutect2
- TFR2 | c.967-32G>A | Intron (SNP) | VAF 28/194 reads (14%) | catalogued as rs780816037; called by muse, mutect2, varscan2
